Surgical pathology report (de-identified scan), TCGA case TCGA-HM-A4S6, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-HM-A4S6-01A (Primary Tumor).

[page 1 of 2]
Final Surgical Pathology Report

Procedure:

Diagnosis

A. Uterus, cervix, resection:

Invasive squamous cell carcinoma, poorly differentiated, 6.5 cm.

Squamous cell carcinoma in situ focally extends to the cervical cuff margin, (6-9 o'clock).

Lymphovascular space invasion by carcinoma identified

Uterus, endometrium, resection:

No pathologic diagnosis

Uterus, myometrium, resection:

No pathologic diagnosis

Ovaries, right and left, resection:

No pathologic diagnosis

Fallopian tubes, right and left, resection:

No pathologic diagnosis.

B. Right pelvic lymph nodes, resection:

Metastatic carcinoma in 1 of 6 lymph nodes (1/6).

C. Right periaortic lymph nodes, resection:

No evidence of metastasis in 4 lymph nodes (0/4).

D. Left pelvic lymph nodes, resection:

Metastatic carcinoma in 1 of 1 lymph node (1/1).

E. Left periaortic lymph nodes, resection:

No evidence of metastasis in 2 lymph nodes (0/2).

ICD-O-3

Carcinoma, squamous cell, NOS
8070/3

Site: cervix, NOS C53.9

hw
10/26/12

Microscopic Description:

Microscopic examination performed.

A. Histologic type: Invasive squamous cell carcinoma of the cervix

Histologic grade: Poorly differentiated

Primary tumor (pT) TNM (FIGO): 6.5 cm, pT1b2. FIGO IB2

Margins of resection:

Distance of tumor to closest margin: Less than 0.5 mm from inked circumferential margin

Presence of carcinoma in situ at distal margin: Squamous carcinoma in situ is present in the cervical cuff margin between 6 and 9:00

Vascular invasion: Present

Regional lymph nodes (pN): Metastatic carcinoma is present in one right and one left pelvic lymph node, N1

Distant metastasis (pM): Cannot be evaluated by the specimen, pMX

Other findings: None

B. The right pelvic lymph nodes demonstrate metastatic carcinoma in 1 of 6 nodes.

~~C. The right periaortic lymph nodes demonstrate no evidence of metastasis in 4 lymph nodes.~~

D. The left pelvic lymph nodes demonstrate metastatic squamous cell carcinoma in 1 of 1 lymph node.

E. The left periaortic lymph nodes demonstrate no evidence of metastasis in 2 lymph nodes.

Specimen

A. Uterus, cervix, tubes and ovaries, right parametrium

B. Right lymph nodes, pelvic

C. Right periaortic lymph node

D. Left pelvic lymph nodes

E. Left periaortic lymph node

Clinical Information

Cervical carcinoma

Intraoperative Consultation

AFS1, AFS2, AFS3 - uterus, cervix, resection: Invasive Squamous Cell Carcinoma.

[page 2 of 2]
Gross Description

A. Received fresh labeled "uterus, cervix, tubes and ovaries, right parametrium" is a 249 g, 8.5 x 5.3 x 4.7 cm symmetrical uterine corpus with attached, markedly expanded, 6.5 cm cervix and bilateral adnexa. The serosa is smooth to scabrous tan-pink-red. A scant amount of soft tan-pink-gold parametrial tissue is present along the right and left lateral aspects. The cervix measures 5.5 cm from right to left and 5.3 cm from anterior to posterior. The anterior surface is inked blue and the posterior surface is inked black. The annular 5.3 cm ectocervix ranges from smooth tan-white to glistening white-pink in keeping with tumor. A thin rim of wrinkled tan-white vaginal mucosa circumferences the ectocervical margin. The specimen is opened along the lateral aspects to show a circumferential soft tan-white cervical tumor. A portion of the tumor and a portion of normal are submitted for tissue procurement as requested. A frozen section is performed. On sectioning, the tumor has a maximal thickness of 3 cm (invasive thickness), however tumor replaces the entire 6.5 cm cervix. Carcinoma extends to within less than 0.1 cm of the inked posterior surface. The triangular 4.5 x 3.2 cm uterine cavity is lined by flat tan-pink-red endometrium averaging 0.2 cm. The myometrium is smooth tan-pink and measures up to 2.3 cm. A single, 0.8 cm tan-white intramural leiomyoma is present anteriorly (see block 15). The rubbery tan-pink right and left ovaries average 2.8 x 1.8 x 1.2 cm. The stroma of both ovaries is pale tan with identifiable corpora albicantia. A few cystic structures measuring up to 0.7 cm are present within the left ovary. The centrally discontinuous tan-pink right and left fallopian tubes average 6.5 cm in length and range from 0.4-0.7 cm in diameter. RS 20
Summary: 1 - 12-3 o'clock cervical cuff, 2 - 3 - 6 o'clock cervical cuff, 3 - 6 - 9 o'clock cervical cuff, 4 - 9 - 12 cervical cuff, 5 and 6 - 12 o'clock cervix/Lus, 7 and 8 - 3 o'clock cervix/Lus, 9 and 10 o'clock - 6 o'clock cervix/Lus, 11 and 12 - 9 o'clock cervix/Lus, 13 and 14 - posterior cervix tumor to closest inked surface, 15 - anterior endomyometrium, 16 - posterior endomyometrium, 17 - right adnexa, 18 - left adnexa, 19 - right parametrium, 20 - left parametrium

B. Received fresh labeled "right lymph nodes, pelvic" is a 7.7 x 6.5 x 3.2 cm aggregate of soft tan gold adipose tissue. Several soft to slightly rubbery tan-pink-gold tissues in keeping with lymph nodes measuring up to 3.3 cm in greatest dimension are recovered. The lymphoid tissues are entirely submitted in 9 blocks
Summary: 1 - 2 lymph nodes, 2 through 5 - 1 bisected lymph node per cassette, 6 through 9 - largest lymph node

C. Received fresh labeled "right periaortic lymph node" is a 2.7 x 1.7 x 0.4 cm aggregate of soft, lobulated tan gold adipose tissue which appears to contain 3 soft tan-pink tissues in keeping with lymph nodes measuring up to 0.7 cm. The lymphoid tissues are submitted in toto in one block.

D. Received fresh labeled "left pelvic lymph nodes" is a 5.9 x 5.5 x 2.2 cm aggregate of soft, lobulated tan gold adipose tissue. A single, ovoid, 2.1 cm soft to slightly rubbery tan-pink-gold tissue in keeping with lymph node is recovered. The lymphoid tissue is bisected and entirely submitted in 2 blocks.

E. Received fresh labeled "left periaortic lymph node" is a 2.1 x 2.0 x 0.8 cm aggregate of soft tan gold adipose tissue. No definitive lymphoid tissues are recovered. AS1

	Yes	No
INDEX		
Site Discrepancy		
History		
Primary Note		
UNQUALIFIED		

10/26/12

Source: NCI Genomic Data Commons file cce92e82-49d6-49c5-9300-0f2893c6a05f (TCGA-HM-A4S6.B4118FB2-3A61-44B4-BC2F-020EB53542A1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).